Gene-level copy-number profile of tumor specimen TCGA-49-6743-01A from TCGA case TCGA-49-6743, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 81.6 years (29,807 days).
Specimen TCGA-49-6743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bab8b5b7-c3d3-4aa1-a3a6-a1717619de4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-6743-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99038045-afc7-409c-ae28-624f67fc17fa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 1,406; copy number 2: 22,797; copy number 3: 19,174; copy number 4: 9,287; copy number 5: 4,679; copy number 6: 1,484; copy number 8: 246; copy number 9: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-6743-01A-11D-1854-01): tumor purity 0.27, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:91,843,687–95,284,575, 37 genes (within-gene range 0–2): PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1, MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,119 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–60,802,086, 956 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr12:37,575,587–51,923,361, 343 genes, copy number 6 (broad region; genes not listed).
- chr12:52,380,460–57,296,484, 291 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:64,507,001–64,697,564, 1 gene, copy number 6 (within-gene range 2–6): RASSF3.
- chr12:64,575,665–65,826,997, 31 genes, copy number 6: SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52.
- chr12:65,830,750–65,831,050, 1 gene, copy number 6: AC107308.1.
- chr12:109,573,255–110,218,793, 20 genes, copy number 6 (within-gene range 2–6): MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1, TCHP, GIT2, AC084876.1, AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2, IFT81.
- chr12:115,263,170–119,681,624, 84 genes, copy number 6–8 (broad region; genes not listed).
- chr12:120,914,400–133,214,832, 383 genes, copy number 6–8 (broad region; genes not listed).
- chr13:50,909,747–114,337,626, 742 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr18:7,566,782–9,254,346, 28 genes, copy number 5 (within-gene range 2–5): PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1.
- chr18:22,699,481–29,361,963, 101 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:47,778,585–58,605,223, 824 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
